Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6163, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6163-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

Moderately differentiated adenocarcinoma in the sigmoid colon. No history of chemoradiation.

Specimens Submitted:

- 1: SP: Sigmoid colon; resection
- 2: SP: Proximal margin
- 3: SP: Distal margin

DIAGNOSIS:

- 1. SP: Sigmoid colon; resection:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Sigmoid colon

Tumor Size:

Length is 1.1 cm

Width is 0.7 cm

Maximal thickness is 0.4 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Not identified

Deepest Tumor Invasion:

Submucosa

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

** Continued on next page **

[page 2 of 3]
Hyperplastic polyp; number: 1
Non-Neoplastic Bowel:
Diverticulosis
Lymph Nodes:
Number with metastasis: 0
Total number examined: 23
Tumor deposits in pericolic soft tissue:
Not Identified
Tumor Staging (AJCC 7th Edition):
pT1 (Tumor invades submucosa)
Lymph Node Stage (AJCC 7th Edition):
N0 (No regional lymph node metastasis)

2. SP: PROXIMAL MARGIN, EXCISION:
- BENIGN COLONIC TISSUE.
3. SP: DISTAL MARGIN, EXCISION:
- BENIGN COLONIC TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1. The specimen is received fresh, labeled "sigmoid colon" and consists of a segment colon measuring 16.2cm in length with a circumference of 5.0 cm at the stapled resected margin and 4.8 cm the open resected margin. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 1.5 cm in thickness. The specimen is opened to reveal an ulcerated mass lesion measuring 1.1 cm in length and 0.7 cm in width. The mass is located 10.0 cm from the stapled margin and 6.3 cm from the open margin. Sectioning shows that the tumor invades the submucosa. The depth of invasion is 0.4 cm grossly. There is a 0.1 cm polyp located 3.0 cm from the open resection margin. There are several diverticuli with associated muscular wall and pericolic adipose tissue thickening. The remaining mucosa is grossly unremarkable. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:
S - stapled margin shave
O - open margin shave
T tumor, entirely
RS - 0.1 cm polyp and representative section from colon
DIV- diverticuli
LN - lymph nodes

** Continued on next page **

[page 3 of 3]
2). The specimen is received in formalin, labeled "Proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a white plastic piece is noted. A ring of pink tan soft tissue is attached measuring 1.8 x 1.5 x 1 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U undesignated

3). The specimen is received in formalin, labeled "Distal margin" and consists of a ring of pink tan soft tissue measuring 2.5 x 1.5 x 0.7 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:
Part 1: SP: Sigmoid colon; resection

Block	Sect.	Site	PCs
2		div	2
5		ln	4
1		o	1
1		rs	1
1		s	1
2		t	2

Part 2: SP: Proximal margin

Block	Sect.	Site	PCs
1		U	1

Part 3: SP: Distal margin

Block	Sect.	Site	PCs
1		U	1

** End of Report **

Source: NCI Genomic Data Commons file 3c5cacfe-f7e3-4e03-8892-6b30eb859ef5 (TCGA-CM-6163.E4807035-D100-4469-A21E-DA16401DF24B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).